CCDI case PBCLCT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/eec9bd9e-e132-452a-9520-6bef99c3a9c5

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Pigmented dermatofibrosarcoma protuberans: ICD-O-3 morphology code: 8833/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 11.6 years (4,242 days).

Biospecimens (3 samples)
- Sample 0DV4IO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV4IX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DV4KS: Tissue type: Tumor; Specimen type: Solid Tissue.
